Surgical pathology report (de-identified scan), TCGA case TCGA-91-6831, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6831-01A (Primary Tumor).

[page 1 of 2]
Final Pathologic Diagnosis:

A. Lymph node, lower paratracheal #4, excision:

No significant pathologic change.

Lymph node, subcarinal #7, excision:

No significant pathologic change.

Lymph node, inferior pulmonary ligament #9, excision:

Follicular hyperplasia.

Lymph node, intrapulmonary #12, excision:

Calcified fibrous nodule.

B. Lung, right middle and lower, bilobectomy:

Poorly differentiated adenocarcinoma (T2N0Mx).

Maximum tumor dimension 6 cm.

Bronchial margin free of tumor.

Lymph node, right lobar/intralobar, excision:

No significant pathologic change.

Myocardium, not otherwise specified, biopsy:

Fibrous adhesions.

C. Lung, right upper lobe, biopsy:

Mild emphysema with respiratory bronchiolitis.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

***Electronically Signed ***

, M.D.

, M.D.

Gross Description:

Received are three formalin-filled containers labeled with the patient's name,

" ."

Part A is additionally labeled "lymph node box--right." The specimen is submitted in a multi-welled container with all tissue submitted in the portion of the box labeled "right lung."

In the compartment labeled "#4, lower paratracheal," there are two lymph node candidates, each 0.4 cm in greatest dimension. They are submitted in toto in cassette A1.

The portion of the box labeled "#7, subcarinal" contains two portions of pink-tan soft tissue, 4.0 x 3.0 x 1.0 cm in aggregate. There are calcifications present within this tissue which are not submitted. There is a single lymph node candidate, 2.0 x 1.0 x 0.5 cm in dimension. It is bisected and submitted in toto in cassettes A2 and A3.

In the compartment labeled "#9, inferior pulmonary ligament," there is a single lymph node candidate, 1.2 x 0.6 x 0.4 cm. It is bisected and submitted in toto in cassette A4.

In the compartment labeled "#12, (intrapulmonary)" is a single lymph node candidate, 0.4 x 0.2 x 0.2 cm. It is submitted in toto in cassette A5.

[page 2 of 2]
Part B is additionally labeled "right bilobectomy (middle and lower lobes)." The specimen consists of a 360 g middle and lower lobe of right lung. The anterior portion of the right lower lobe contains a 6.0 x 4.0 x 5.0 cm mass. It is irregular and appears to be composed of multiple nodules. It is grossly 2.0 cm from the bronchial margin and extends into the fissure with the adjacent middle lobe. The most anterior aspect of the tumor is umbilicated. The pleural surface is inked in black. The bronchial margin is submitted in cassette B1. The vascular margin is submitted in cassette B2. The cross section of the tumor reveals a multilobated white-gray and yellow mass with foci of hemorrhage. A section transversing the oblique fissure is submitted in cassette B3. Additional sections of mass are submitted in cassettes B4-B6. Representative sections of uninvolved lower lobe are submitted in cassette B7. The uninvolved parenchyma is congested but not appreciably emphysematous. The lingular portion of the middle lobe features a calcification, 1.0 cm in greatest dimension. No section of calcification is submitted. A representative section of uninvolved middle lobe is submitted in cassette B8. A single lymph node candidate is identified. It is 1.9 x 0.6 x 0.5 cm. It is bisected and submitted in toto in cassette B9.

Part C is additionally labeled "right upper lobe." The specimen consists of a portion of lung tissue, 2.5 x 1.0 x 0.4 cm. No definitive lesion is identified. The specimen is step-sectioned and submitted in toto in cassettes C1 and C2.

, M.D.

Microscopic Description:

Sections of the vascular margin demonstrates a portion of apparently adherent myocardium, without significant pathologic change. The tumor appears to involve the visceral pleura. Foci are suspicious for lymphovascular invasion. There is respiratory bronchiolitis and emphysematous change in the main specimen as well.

Taken: [REDACTED]

Source: NCI Genomic Data Commons file b47354cf-2f5a-47e7-b307-9c94956078d8 (TCGA-91-6831.21F30AB4-751E-4EF5-BFFA-75D5086EA1CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).